Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACD-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver: 21.0 x 16.5 x 10.0 cm, unfixed

Gallbladder: 9.0 cm in length, 3.2 cm in diameter, and 2.0 mm in wall thickness, unfixed

2. Tumor location: right

Tumor number: one

Tumor size: 12.0 x 15.0 x 12.0 cm

3. Satellite nodule: yes

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes (20 %)

6. Hemorrhage/peliosis: yes (20 %)

7. Portal vein invasion: yes

8. Bile duct invasion: no

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JAS 5/19/14

Gross photo present.

Blocks

T1-7, liver mass x 7

A, non-tumorous lesion x 1

RM, resection margin x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation IV/IV

The major differentiation III

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Fibrous capsule formation: no

3. Septum formation: no

4. Surgical resection margin invasion: no, margin of the clearance (0.7 cm)

5. Serosal invasion: no

6. Portal vein invasion: yes

7. Bile duct invasion: no

[page 2 of 3]
- 8. Hepatic vein invasion: no
- 9. Hepatic artery invasion: no
- 10. Microvessel invasion: yes
- 11. Intrahepatic metastasis: yes
- 12. Multicentric occurrence: no

Non-tumor liver pathology

- 1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: minimal
- 1-4. Stage (fibrosis): periportal
- 1-5. Cirrhosis: no
- 2. Dysplastic nodule: no
- 3. Ductal epithelial dysplasia: no
- 4. Other liver diseases: no

NOT reported. Gross:

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005
Lymph node, regional, biopsy, reactive hyperplasia
T08000, regional, P50, M72200

DIAGNOSIS:

Liver, right, hemihepatectomy:
Hepatocellular carcinoma, moderately differentiated
Gallbladder, cholecystectomy:
Chronic cholecystitis
Lymph node, regional, biopsy:
Reactive hyperplasia (0/1)

NOTE:

Recommend to order the IHC stains (Hepatocyte, CK7 and CK19) for block T2.

[page 3 of 3]
Suggestion :

Source: NCI Genomic Data Commons file 2aefe7c8-fbef-4cd9-9373-9e97a2581f19 (TCGA-DD-AACD.0494EF97-6D76-4DC7-8642-880C889C2C24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).